TCGA case TCGA-28-1751 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/28df4629-204f-4352-a19f-303a2e067633

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 61.0 years (22,291 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 58 days; Treatment dose: 5,940 cGy; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 208 days; Number of cycles: 3; Treatment dose: 2,100 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 208 days; Number of cycles: 3; Treatment dose: 6,300 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 208 days; Number of cycles: 3; Treatment dose: 2,600 mg; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Dendritic Cell Vaccine; Treatment intent type: Adjuvant; Days to treatment start: 114 days; Days to treatment end: 142 days.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 61.6 years (22,510 days); Days to diagnosis: 219 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day 219 (post initial treatment): Progression or recurrence: Yes; Days to progression: 219 days.
- Days to follow up: 232 days; Disease response: With Tumor.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-28-1751-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.9; Shortest dimension: 0.8.
  Slide TCGA-28-1751-01A-01-BS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 15; Percent stromal cells: 5.
  Slide TCGA-28-1751-01A-02-BS2: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 10.
- Sample TCGA-28-1751-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-28-1751-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Dendriticcell Vaccine.
- Drug treatment 1, Route of administrations: Route of administration: Other (specify below).
- Drug treatment 2, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 232 days; disease-specific survival: no event (censored), 232 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 219 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-28-1751-01A-02D-0591-01): tumor purity 0.38, ploidy 2.06, whole-genome doublings 0.
